Somatic mutation profile of tumor specimen 0DQB2U from CCDI case PBCEEB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,724 days).
Specimen 0DQB2U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4144ebc3-0aae-438a-ab13-8c6fd28c3683.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB21 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7b18896-489f-43fe-8932-52c427e1759d

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C9orf64 | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs746617555; called by muse, mutect2, varscan2
- OGFOD2 | c.859G>A p.G287S (on ENST00000228922 / NM_001304833.1; = p.G227S on NM_024623.3) | Missense Mutation (SNP) | VAF 98/295 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as rs1358910932; called by muse, mutect2, varscan2
- CFAP45 | c.1593C>T p.P531= | Silent (SNP) | VAF 66/200 reads (33%) | catalogued as rs1381327954; called by muse, varscan2
- OR7G3 | c.561C>T p.L187= | Silent (SNP) | VAF 73/202 reads (36%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.2604G>A p.P868= | Silent (SNP) | VAF 53/300 reads (18%) | catalogued as rs551924151, COSV57794692; called by muse, mutect2, varscan2
- NPAP1L | n.988G>A | RNA (SNP) | VAF 71/334 reads (21%) | catalogued as rs1247595866; called by muse, mutect2, varscan2
